Gene-level copy-number profile of tumor specimen TCGA-AA-3496-01A from TCGA case TCGA-AA-3496, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 83.3 years (30,438 days).
Specimen TCGA-AA-3496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e508b3a5-84ff-490a-899b-5a421d1e1f07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3496-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89652275-811f-438d-9f84-1a7652471f32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 6,844; copy number 2: 39,698; copy number 3: 12,218; copy number 5: 36; copy number 6: 996.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3496-01A-21D-1834-01): tumor purity 0.73, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,333,546–43,620,984, 28 genes (within-gene range 0–3): COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,032 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:125,859,721–126,292,788, 1 gene, copy number 5 (within-gene range 3–5): LINC00861.
- chr8:126,072,587–128,187,101, 35 genes, copy number 5 (within-gene range 3–5): KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr20:20,854,121–21,755,350, 28 genes, copy number 6: MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1.
- chr20:24,931,840–64,313,132, 968 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
